Somatic mutation profile of tumor specimen C3L-06091-03 (aliquot CPT0361150009) from CPTAC case C3L-06091, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 45.9 years (16,759 days).
Specimen C3L-06091-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c615b1b7-9702-4cde-9a78-e1bda78a331b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06091-31 (Blood Derived Normal), aliquot CPT0361230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13324baa-6695-4078-8d77-517db4b1f1bb

The open-access MAF lists 360 somatic variants for this specimen: 233 protein-altering or splice-affecting, 119 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 119, Nonsense Mutation 16, Intron 6, Splice Region 3, Frame Shift Del 2, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 54/272 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNC | c.4969C>T p.R1657* | Nonsense Mutation (SNP) | VAF 81/349 reads (23%) | catalogued as rs1563000044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PRDM6 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 19/301 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs879255278, CM166493, COSV68337766; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS20 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67134539; called by muse, mutect2, varscan2
- ADGRB1 | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV60094504, COSV99075406; called by muse, mutect2, varscan2
- ADGRL3 | c.4507G>A p.E1503K (on ENST00000506720 / NM_001322402.2; = p.E1392K on NM_015236.6) | Missense Mutation (SNP) | VAF 92/398 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); catalogued as rs1560581815, COSV72229489; called by muse, mutect2, varscan2
- ADGRV1 | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV67982085; called by muse, mutect2, varscan2
- ADGRV1 | c.9109C>T p.P3037S | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67984728; called by muse, mutect2, varscan2
- ADGRV1 | c.9439C>T p.R3147* | Nonsense Mutation (SNP) | VAF 37/133 reads (28%) | catalogued as rs769681955, COSV67985825; called by muse, mutect2, varscan2
- AGL | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768133891, COSV54057814; called by muse, mutect2, varscan2
- ALDH8A1 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776026319, COSV55640483; called by muse, mutect2, varscan2
- ANP32D | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs753147438; called by muse, mutect2, varscan2
- ARSH | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369096338, COSV66962770; called by muse, mutect2, varscan2
- CCDC158 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 117/433 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs780371226, COSV66355760, COSV66356205; called by muse, mutect2, varscan2
- CD6 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs776414916; called by muse, mutect2, varscan2
- CFAP47 | c.8683C>T p.P2895S | Missense Mutation (SNP) | VAF 77/313 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.051); catalogued as rs1340429614; called by muse, mutect2, varscan2
- CFAP54 | c.7018G>A p.E2340K | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61571073; called by muse, mutect2, varscan2
- CGNL1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55564772; called by muse, mutect2, varscan2
- CLSTN2 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 87/379 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as COSV71723736; called by muse, mutect2, varscan2
- COL4A1 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011641; called by muse, mutect2, varscan2
- COL5A3 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 104/405 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99319830; called by muse, mutect2, varscan2
- CUL4B | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 82/346 reads (24%) | catalogued as CM151182, COSV60689694; called by muse, mutect2, varscan2
- CX3CR1 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV64195060; called by muse, mutect2, varscan2
- CYB561D1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs141356973; called by muse, mutect2, varscan2
- DNER | c.1100C>A p.A367E | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.258); catalogued as COSV59174461; called by muse, mutect2, varscan2
- DSC1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 97/350 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV57152165; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- ELAPOR2 | c.2156T>C p.L719S (on ENST00000450689 / NM_001142749.3; = p.L552S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254877491; called by muse, mutect2, varscan2
- EPC2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as rs764780426, COSV51542549; called by muse, mutect2, varscan2
- EPHA7 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs750462795, COSV65177938; called by muse, mutect2, varscan2
- EPRS1 | c.3991C>T p.R1331* | Nonsense Mutation (SNP) | VAF 78/407 reads (19%) | catalogued as COSV65098391; called by muse, mutect2, varscan2
- F2RL3 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs535600701, COSV50185660, COSV99935330; called by muse, mutect2, varscan2
- FAM135B | c.4072G>A p.D1358N | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs769486878, COSV52754761; called by muse, mutect2, varscan2
- FAM83B | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 83/393 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs145623856; called by muse, mutect2, varscan2
- FBXO47 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100960577, COSV65241164; called by muse, mutect2, varscan2
- FGD5 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 111/398 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.039); catalogued as COSV99549689; called by muse, mutect2, varscan2
- FGD6 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs751217978, COSV59690883; called by muse, mutect2, varscan2
- FHAD1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1362855448; called by muse, mutect2, varscan2
- FILIP1 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 82/296 reads (28%) | catalogued as rs778800256, COSV52726160; called by muse, mutect2, varscan2
- FRAS1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs373637160; called by muse, mutect2, varscan2
- FUT9 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV56147478; called by muse, mutect2, varscan2
- GPRASP2 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 148/482 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV59991924; called by muse, mutect2, varscan2
- GRIK2 | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs749785819, COSV59737454; called by muse, mutect2, varscan2
- GRXCR1 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV104433308; called by muse, mutect2, varscan2
- HNF4A | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs145902391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNF4G | c.829C>T p.R277W (on ENST00000354370 / NM_001330561.2; = p.R324W on NM_004133.5) | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759216473, COSV62966120; called by muse, mutect2, varscan2
- HYDIN | c.12214C>T p.P4072S | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765109053; called by muse, mutect2, varscan2
- ITPR2 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.816); catalogued as COSV101190120; called by muse, mutect2, varscan2
- KCNH6 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 88/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776555763, COSV59002435; called by muse, mutect2, varscan2
- KCNJ14 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs532186279, COSV60737950; called by muse, varscan2
- KIF26B | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 148/783 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs778060391; called by muse, mutect2, varscan2
- KLHL30 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as rs773304639, COSV59975569; called by muse, mutect2, varscan2
- KRTAP5-7 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 114/406 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1397920886; called by muse, varscan2
- LAD1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 269/568 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs373631310; called by muse, mutect2, varscan2
- LRRC66 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 131/491 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs1386089291, COSV58632238, COSV58637421; called by muse, mutect2, varscan2
- LTF | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51606643; called by muse, varscan2
- MAGEC1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 99/503 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as rs764426413; called by muse, mutect2, varscan2
- MID1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 161/568 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs866240677, COSV58193214; called by muse, mutect2, varscan2
- MTNR1A | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 67/348 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV100208286; called by muse, mutect2, varscan2
- MUC16 | c.11304G>A p.M3768I | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV67492130; called by muse, mutect2, varscan2
- MVP | c.2266-1G>A p.X756_splice | Splice Site (SNP) | VAF 82/284 reads (29%) | catalogued as rs1420778253; called by muse, mutect2, varscan2
- MYH1 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs769516692, COSV56857382, COSV99877133; called by muse, mutect2, varscan2
- MYOM3 | c.1966A>C p.T656P | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs1336729033, COSV58395131; called by muse, mutect2, varscan2
- NAP1L1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.427); catalogued as rs960661050, COSV99674104; called by muse, mutect2, varscan2
- NKAP | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 159/658 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772645255; called by muse, mutect2, varscan2
- NOX1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs868063945; called by muse, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 75/383 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPAP1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 118/424 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV61504711; called by muse, mutect2, varscan2
- NPAS4 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1391815252, COSV60649410; called by muse, mutect2, varscan2
- NTM | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV100866991; called by muse, mutect2, varscan2
- OR4K14 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59292858; called by muse, mutect2, varscan2
- OR4Q2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs1190649339; called by muse, mutect2, varscan2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 130/427 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2, varscan2
- OR5D13 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV62335775; called by muse, varscan2
- OTOGL | c.4590G>A p.W1530* (on ENST00000547103; = p.W1521* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 58/215 reads (27%) | catalogued as COSV54020660; called by muse, mutect2, varscan2
- PALLD | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1391979108; called by muse, mutect2, varscan2
- PCDHA12 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 18/559 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs782526620, COSV56525897; called by muse, mutect2
- PCDHB7 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 137/486 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50801249; called by muse, mutect2, varscan2
- PCLO | c.12377A>G p.H4126R | Missense Mutation (SNP) | VAF 101/355 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs778643722; called by muse, mutect2, varscan2
- PCLO | c.11060C>T p.P3687L | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs764535197; called by muse, mutect2, varscan2
- PIK3CG | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs777538453; called by muse, mutect2, varscan2
- PKHD1 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV100582984; called by muse, mutect2, varscan2
- PKHD1L1 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV65736104; called by muse, mutect2, varscan2
- PLCG2 | c.3697A>G p.K1233E | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs765126381; called by muse, mutect2, varscan2
- POF1B | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99426499; called by muse, mutect2, varscan2
- POLI | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1432374662; called by muse, mutect2, varscan2
- PREX2 | c.3955C>T p.H1319Y | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV55762281; called by muse, mutect2, varscan2
- PTPRT | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 101/321 reads (31%) | catalogued as rs267605939, COSV61982017, COSV61986603; called by muse, mutect2, varscan2
- SEMA3A | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs866354226, COSV54894115; called by muse, mutect2, varscan2
- SERINC2 | c.680A>G p.Y227C (on ENST00000373709 / NM_178865.5; = p.Y231C on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/453 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1553133701, COSV65489692; called by muse, mutect2, varscan2
- SERPINA9 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 101/418 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs748943432; called by muse, mutect2, varscan2
- SHANK2 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 100/449 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1555153976, COSV53593387; called by muse, mutect2, varscan2
- SLC22A9 | c.1071G>A p.T357= | Splice Region (SNP) | VAF 42/188 reads (22%) | catalogued as rs150251554; called by muse, mutect2, varscan2
- SLC35F3 | c.338C>T p.P113L (on ENST00000366617 / NM_001300845.1; = p.P182L on NM_173508.4) | Missense Mutation (SNP) | VAF 93/451 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64019805; called by muse, mutect2, varscan2
- SPANXN2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 215/824 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as COSV65127699; called by muse, mutect2
- STARD8 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 160/528 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1163491682; called by muse, mutect2, varscan2
- STXBP5L | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV56510578; called by muse, mutect2, varscan2
- SYMPK | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs201272896, COSV99841611; called by muse, mutect2, varscan2
- TAGAP | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV57853093; called by muse, mutect2, varscan2
- TBC1D9 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757700003, COSV65932265; called by muse, mutect2, varscan2
- TECRL | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs752713102; called by muse, mutect2, varscan2
- TET3 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 148/542 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV59882970; called by muse, mutect2, varscan2
- TEX13C | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 134/593 reads (23%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.587); catalogued as rs1232155117; called by muse, mutect2, varscan2
- TJP3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53661023; called by muse, mutect2, varscan2
- TMEM121B | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 153/638 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1206766738; called by muse, mutect2, varscan2
- TMEM132C | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 130/525 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.069); catalogued as rs1167681088; called by muse, mutect2, varscan2
- UGT2B28 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV59430819, COSV59433399; called by muse, mutect2, varscan2
- USH2A | c.14011G>A p.E4671K | Missense Mutation (SNP) | VAF 109/526 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs769560933, COSV56326302; called by muse, mutect2, varscan2
- USH2A | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 76/370 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV56420506; called by muse, mutect2, varscan2
- VPS13B | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62017082; called by muse, mutect2, varscan2
- VRTN | c.2093C>T p.T698I | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1333685835; called by muse, mutect2, varscan2
- XIRP1 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 117/435 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1319786697; called by muse, mutect2, varscan2
- XPO6 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58972490; called by muse, mutect2, varscan2
- ZFP42 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs866099446, COSV58817784; called by muse, mutect2, varscan2
- ZNF157 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 119/521 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV65659672; called by muse, mutect2, varscan2
- ZNF609 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 91/411 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as rs765310375; called by muse, mutect2, varscan2
- ZNF845 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs569331218, COSV72004250; called by muse, mutect2, varscan2
- ZNF99 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68056736; called by muse, mutect2, varscan2
- ABCA1 | c.5930T>G p.I1977S | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADAM23 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM7 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADCY5 | c.3734G>A p.G1245D | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF3 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AGAP3 | c.45+8C>T | Splice Region (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2
- AGBL2 | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- AKAP17A | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 212/746 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ALS2CL | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMY2A | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 84/421 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ARID1A | c.3262G>A p.A1088T | Missense Mutation (SNP) | VAF 127/426 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ATG9B | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 121/389 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ATP11B | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AZIN2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 119/412 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BCAN | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BCLAF1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 77/577 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C3 | c.1970G>T p.R657M | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- C7 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CABP2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1C | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CATSPERE | c.2450T>G p.L817R | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CCDC168 | c.13900C>T p.Q4634* | Nonsense Mutation (SNP) | VAF 97/344 reads (28%) | called by muse, mutect2, varscan2
- CCDC168 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CD3G | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- CILP2 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 139/512 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- COL6A5 | c.6283G>A p.E2095K (on ENST00000312481; = p.E2091K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CPOX | c.707T>A p.L236* | Nonsense Mutation (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- CRB1 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CUX2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CYLC1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- DEGS2 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DLL4 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 103/419 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EFNB3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 77/319 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ESYT2 | c.551C>T p.P184L (on ENST00000613624; = p.P108L on NM_020728.3) | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FBXL15 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 128/334 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FEZF1 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 104/394 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- FIG4 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FSIP2 | c.13582G>A p.E4528K | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GRM3 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 143/507 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAUS7 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 125/539 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HIVEP1 | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 200/459 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HIVEP1 | c.4058C>T p.T1353I | Missense Mutation (SNP) | VAF 70/491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCLL1 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 105/485 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HPS3 | c.2156A>C p.Q719P | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2
- IMPG2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAD | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ITGAE | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- IVL | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 111/663 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- KIR2DS4 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KLHL21 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 141/498 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KLHL4 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 80/336 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNL1 | c.5980G>A p.G1994R (on ENST00000346991 / NM_170589.5; = p.G1968R on NM_144508.5) | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR6 | c.2301G>A p.W767* (on ENST00000367278 / NM_001017403.1; = p.W715* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 122/597 reads (20%) | called by muse, mutect2, varscan2
- LHCGR | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- LIMK1 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 125/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRFN4 | c.1526_1542del p.L509Rfs*134 | Frame Shift Del (DEL) | VAF 131/626 reads (21%) | called by mutect2, pindel, varscan2
- MAP3K6 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPK14 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- MGAM2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MUC16 | c.27338G>A p.G9113E | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.534); called by muse, mutect2
- MUC17 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 97/441 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- MUC5B | c.16669G>A p.V5557M | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO5B | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- MYO7B | c.2340G>A p.R780= | Splice Region (SNP) | VAF 74/295 reads (25%) | called by muse, mutect2, varscan2
- N4BP1 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- NABP1 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NEK4 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 134/476 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSD2 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 91/375 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- NUMA1 | c.3641C>T p.A1214V | Missense Mutation (SNP) | VAF 100/389 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- OBSCN | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- OR10G4 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 56/618 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- OR10G9 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR10H1 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 136/465 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR52K1 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PACS1 | c.1958G>A p.W653* | Nonsense Mutation (SNP) | VAF 78/367 reads (21%) | called by muse, mutect2, varscan2
- PAIP2B | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PAPPA2 | c.4774C>T p.P1592S | Missense Mutation (SNP) | VAF 103/470 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PDSS2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PIK3C2G | c.3494G>A p.G1165E (on ENST00000676171; = p.G1124E on NM_004570.5) | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEE | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 155/649 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRDM16 | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 114/490 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2
- PRR3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 271/636 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RAD54B | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELB | c.1139T>A p.F380Y | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, varscan2
- RELB | c.1140_1141del p.L381Afs*22 | Frame Shift Del (DEL) | VAF 95/399 reads (24%) | called by muse*, mutect2, varscan2*
- RGPD4 | c.3236A>G p.E1079G | Missense Mutation (SNP) | VAF 158/551 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RMND5B | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF216 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RSPH3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 156/534 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SELENOV | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 150/569 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SEMG1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SETD1A | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 158/504 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHROOM4 | c.3509G>A p.G1170D | Missense Mutation (SNP) | VAF 118/481 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.199); called by muse, varscan2
- SLC28A2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 64/270 reads (24%) | called by muse, mutect2, varscan2
- SNAP25 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SNX14 | c.1891C>G p.H631D (on ENST00000314673 / NM_001350535.1; = p.H578D on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX29 | c.2026C>T p.H676Y | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPATA31A3 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 136/637 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPEN | c.6382C>T p.Q2128* | Nonsense Mutation (SNP) | VAF 109/402 reads (27%) | called by muse, mutect2, varscan2
- SV2B | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SYNE1 | c.440C>T p.S147F (on ENST00000367255 / NM_182961.4; = p.S154F on NM_033071.3) | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- SYNE2 | c.771A>T p.R257S | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TBX22 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 140/522 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TP53BP2 | c.2590G>A p.V864M (on ENST00000343537 / NM_001031685.3; = p.V735M on NM_005426.2) | Missense Mutation (SNP) | VAF 102/557 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV4-1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRIM56 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 117/468 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRIM69 | c.919C>T p.Q307* (on ENST00000329464 / NM_182985.5; = p.Q148* on NM_080745.5) | Nonsense Mutation (SNP) | VAF 75/357 reads (21%) | called by muse, mutect2, varscan2
- UBQLN4 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 143/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UHRF1BP1 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- USP33 | c.2528C>T p.S843F | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- VAMP4 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- WNK1 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZEB1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF300 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ACSL4 | c.1989G>A p.E663= (on ENST00000340800 / NM_022977.2; = p.E622= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/281 reads (30%) | called by muse, mutect2, varscan2
- ALCAM | c.24C>T p.S8= | Silent (SNP) | VAF 73/275 reads (27%) | called by muse, mutect2, varscan2
- ALG9 | c.1161C>G p.L387= | Silent (SNP) | VAF 65/236 reads (28%) | called by muse, mutect2, varscan2
- ANK1 | c.3192G>A p.V1064= | Silent (SNP) | VAF 102/431 reads (24%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1194C>T p.S398= | Silent (SNP) | VAF 109/339 reads (32%) | catalogued as rs752682439; called by muse, mutect2, varscan2
- ANO5 | c.1746C>T p.F582= | Silent (SNP) | VAF 81/307 reads (26%) | catalogued as rs267602823, COSV61081681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARAP2 | c.42C>T p.F14= | Silent (SNP) | VAF 53/225 reads (24%) | catalogued as rs748150911, COSV58294053; called by muse, mutect2, varscan2
- ARHGAP35 | c.2685C>T p.V895= | Silent (SNP) | VAF 123/417 reads (29%) | catalogued as rs1164788808; called by muse, mutect2, varscan2
- ARHGAP45 | c.2331C>T p.I777= | Silent (SNP) | VAF 96/436 reads (22%) | catalogued as COSV57431724; called by muse, mutect2, varscan2
- ASPRV1 | c.333C>T p.V111= | Silent (SNP) | VAF 126/431 reads (29%) | catalogued as rs774481992, COSV57228374; called by muse, mutect2, varscan2
- BCL11B | c.2259C>T p.S753= (on ENST00000357195 / NM_001282237.2; = p.S682= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 132/520 reads (25%) | catalogued as rs978304353; ClinVar: likely benign; called by muse, mutect2, varscan2
- BPIFB4 | c.552C>T p.L184= | Silent (SNP) | VAF 129/454 reads (28%) | catalogued as rs745539242; called by muse, mutect2, varscan2
- CACNA1E | c.6813C>T p.P2271= (on ENST00000367573 / NM_001205293.3; = p.P2228= on NM_000721.4) | Silent (SNP) | VAF 137/626 reads (22%) | catalogued as COSV100703428; called by muse, mutect2, varscan2
- CDH23 | c.858G>A p.L286= | Silent (SNP) | VAF 58/220 reads (26%) | catalogued as rs1291024666, COSV99819458; called by muse, varscan2
- CEACAM7 | c.120C>T p.V40= | Silent (SNP) | VAF 102/363 reads (28%) | catalogued as rs147314898; called by muse, mutect2, varscan2
- CFAP47 | c.8541G>A p.T2847= | Silent (SNP) | VAF 43/197 reads (22%) | catalogued as rs782478072; called by muse, mutect2, varscan2
- CFAP47 | c.8976G>A p.R2992= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as COSV66220803; called by muse, mutect2, varscan2
- CLDN20 | c.564G>A p.R188= | Silent (SNP) | VAF 90/323 reads (28%) | called by muse, mutect2, varscan2
- CNTN1 | c.144C>T p.I48= | Silent (SNP) | VAF 79/335 reads (24%) | called by muse, mutect2, varscan2
- COL5A3 | c.4257G>A p.E1419= | Silent (SNP) | VAF 108/385 reads (28%) | catalogued as COSV53408618; called by muse, mutect2, varscan2
- COLGALT1 | c.1713C>T p.T571= | Silent (SNP) | VAF 102/399 reads (26%) | catalogued as rs143668245, COSV53111129; called by muse, mutect2, varscan2
- CRNN | c.201G>A p.G67= | Silent (SNP) | VAF 91/492 reads (18%) | called by muse, mutect2, varscan2
- CROCC | c.4485C>T p.T1495= | Silent (SNP) | VAF 117/459 reads (25%) | catalogued as rs1426938174; called by muse, mutect2, varscan2
- CRYBG1 | c.2895G>A p.E965= | Silent (SNP) | VAF 115/367 reads (31%) | called by muse, mutect2, varscan2
- CSMD2 | c.2292C>T p.L764= | Silent (SNP) | VAF 89/339 reads (26%) | catalogued as rs140431671; called by muse, mutect2, varscan2
- CTLA4 | c.276G>A p.G92= | Silent (SNP) | VAF 96/374 reads (26%) | catalogued as COSV99865050; called by muse, mutect2, varscan2
- CUL9 | c.1833C>T p.S611= | Silent (SNP) | VAF 260/594 reads (44%) | called by muse, mutect2, varscan2
- CUX2 | c.1305G>A p.T435= | Silent (SNP) | VAF 101/389 reads (26%) | catalogued as rs770644286; called by muse, mutect2, varscan2
- CXorf66 | c.201C>T p.L67= | Silent (SNP) | VAF 61/264 reads (23%) | catalogued as COSV65169506; called by muse, mutect2, varscan2
- CYP2C9 | c.549C>T p.F183= | Silent (SNP) | VAF 89/225 reads (40%) | called by muse, mutect2, varscan2
- DHX36 | c.2502C>T p.V834= | Silent (SNP) | VAF 63/278 reads (23%) | catalogued as COSV57674105; called by muse, mutect2, varscan2
- DNAH14 | c.339G>T p.S113= | Silent (SNP) | VAF 135/698 reads (19%) | called by muse, mutect2, varscan2
- DNAH5 | c.8860C>T p.L2954= | Silent (SNP) | VAF 11/275 reads (4%) | catalogued as COSV54207598; called by muse, mutect2
- DNAJC16 | c.531C>T p.I177= | Silent (SNP) | VAF 110/320 reads (34%) | catalogued as rs774333530; called by muse, mutect2, varscan2
- ERCC6L | c.2655G>A p.K885= | Silent (SNP) | VAF 104/392 reads (27%) | called by muse, mutect2, varscan2
- FAM47C | c.282G>A p.K94= | Silent (SNP) | VAF 140/519 reads (27%) | catalogued as COSV63723936, COSV63728962; called by muse, mutect2, varscan2
- FAT3 | c.1029C>T p.L343= | Silent (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- FBN2 | c.4083G>A p.G1361= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- FBXO11 | c.2718A>C p.T906= (on ENST00000403359 / NM_001190274.2; = p.T822= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/267 reads (29%) | catalogued as rs533101051; called by muse, mutect2, varscan2
- FER1L5 | c.3903G>A p.R1301= (on ENST00000623019; = p.R1274= on NM_001293083.2) | Silent (SNP) | VAF 123/425 reads (29%) | called by muse, mutect2, varscan2
- FNIP2 | c.2994C>T p.I998= | Silent (SNP) | VAF 89/275 reads (32%) | catalogued as rs770384531; called by muse, mutect2, varscan2
- FUT3 | c.909C>T p.A303= | Silent (SNP) | VAF 52/750 reads (7%) | called by muse, mutect2
- FUT5 | c.948C>T p.A316= | Silent (SNP) | VAF 52/276 reads (19%) | called by muse, mutect2
- GOT1L1 | c.561C>T p.I187= | Silent (SNP) | VAF 73/264 reads (28%) | catalogued as rs746798739, COSV56877096; called by muse, mutect2, varscan2
- GRIK3 | c.2382C>T p.I794= | Silent (SNP) | VAF 111/400 reads (28%) | catalogued as rs1260605103; called by muse, mutect2, varscan2
- GTF3C5 | c.741C>T p.D247= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as COSV59599428; called by muse, mutect2, varscan2
- HEATR1 | c.4233C>T p.F1411= | Silent (SNP) | VAF 110/498 reads (22%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.198C>T p.L66= | Silent (SNP) | VAF 89/368 reads (24%) | catalogued as rs770739964; called by muse, mutect2, varscan2
- JCAD | c.1182G>A p.G394= | Silent (SNP) | VAF 145/421 reads (34%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.582C>T p.Y194= (on ENST00000396284; = p.Y155= on NM_001080770.2) | Silent (SNP) | VAF 154/650 reads (24%) | catalogued as rs1439125442; called by muse, mutect2, varscan2
- KIR3DL1 | c.1218C>T p.F406= | Silent (SNP) | VAF 142/501 reads (28%) | catalogued as COSV58490079; called by muse, mutect2, varscan2
- KLF12 | c.1131C>T p.F377= | Silent (SNP) | VAF 135/399 reads (34%) | called by muse, mutect2, varscan2
- LCE1E | c.36C>T p.P12= | Silent (SNP) | VAF 222/495 reads (45%) | catalogued as COSV64219721; called by muse, mutect2, varscan2
- LDB2 | c.948C>T p.D316= | Silent (SNP) | VAF 115/370 reads (31%) | catalogued as rs775150499, COSV58782789; called by muse, mutect2, varscan2
- LLGL2 | c.681C>T p.F227= | Silent (SNP) | VAF 74/306 reads (24%) | catalogued as COSV51403832; called by muse, mutect2, varscan2
- LMNB2 | c.696G>A p.E232= | Silent (SNP) | VAF 111/399 reads (28%) | called by muse, mutect2, varscan2
- LRRK2 | c.2490G>A p.R830= | Silent (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- MGAM2 | c.6060C>T p.I2020= | Silent (SNP) | VAF 117/480 reads (24%) | catalogued as COSV72176415; called by muse, mutect2, varscan2
- MRGPRD | c.879G>A p.G293= | Silent (SNP) | VAF 77/304 reads (25%) | catalogued as rs772140742, COSV58422829; called by muse, mutect2, varscan2
- MRPL37 | c.642C>T p.N214= | Silent (SNP) | VAF 40/182 reads (22%) | called by muse, mutect2, varscan2
- MTNR1B | c.855C>T p.I285= | Silent (SNP) | VAF 98/390 reads (25%) | catalogued as COSV57066797; called by muse, mutect2, varscan2
- MUC16 | c.15858G>A p.L5286= | Silent (SNP) | VAF 101/417 reads (24%) | called by muse, mutect2, varscan2
- MYH1 | c.4773G>A p.K1591= | Silent (SNP) | VAF 116/384 reads (30%) | catalogued as rs772448178, COSV99876299; called by muse, mutect2, varscan2
- MYH7 | c.4803G>A p.L1601= | Silent (SNP) | VAF 132/532 reads (25%) | catalogued as rs397516228; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYO7B | c.2310C>T p.I770= | Silent (SNP) | VAF 69/276 reads (25%) | called by muse, mutect2, varscan2
- NAP1L1 | c.855T>G p.V285= | Silent (SNP) | VAF 88/413 reads (21%) | called by muse, mutect2, varscan2
- NAP1L5 | c.180G>A p.E60= | Silent (SNP) | VAF 125/430 reads (29%) | catalogued as COSV52017412, COSV52018351; called by muse, mutect2, varscan2
- NEGR1 | c.993C>T p.S331= | Silent (SNP) | VAF 74/304 reads (24%) | called by muse, mutect2, varscan2
- NLRP9 | c.612G>A p.R204= | Silent (SNP) | VAF 94/372 reads (25%) | called by muse, mutect2, varscan2
- NMUR2 | c.288C>T p.L96= | Silent (SNP) | VAF 88/304 reads (29%) | catalogued as COSV54921079; called by muse, mutect2, varscan2
- NUMA1 | c.3642C>T p.A1214= | Silent (SNP) | VAF 99/387 reads (26%) | called by muse, mutect2, varscan2
- ODC1 | c.159G>A p.L53= | Silent (SNP) | VAF 87/372 reads (23%) | catalogued as COSV52171339; called by muse, mutect2, varscan2
- OR10G8 | c.190C>T p.L64= | Silent (SNP) | VAF 109/465 reads (23%) | catalogued as rs768276001; called by muse, mutect2, varscan2
- OR10X1 | c.729G>A p.R243= | Silent (SNP) | VAF 104/470 reads (22%) | catalogued as COSV63767233; called by muse, mutect2, varscan2
- OR4C5 | c.798C>T p.P266= | Silent (SNP) | VAF 78/325 reads (24%) | called by muse, mutect2, varscan2
- OR4K13 | c.255C>T p.F85= | Silent (SNP) | VAF 86/321 reads (27%) | catalogued as rs754907700, COSV59860138; called by muse, mutect2, varscan2
- OR56A1 | c.625T>C p.L209= | Silent (SNP) | VAF 98/350 reads (28%) | called by muse, mutect2, varscan2
- OR5AR1 | c.93C>T p.F31= | Silent (SNP) | VAF 98/342 reads (29%) | called by muse, mutect2, varscan2
- OR6C3 | c.69G>A p.V23= | Silent (SNP) | VAF 72/295 reads (24%) | catalogued as COSV65570612; called by muse, mutect2, varscan2
- OR7G3 | c.135C>T p.I45= | Silent (SNP) | VAF 71/329 reads (22%) | catalogued as rs947857290, COSV100555756; called by muse, mutect2, varscan2
- P2RY4 | c.1017C>T p.S339= | Silent (SNP) | VAF 183/573 reads (32%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4596G>A p.L1532= | Silent (SNP) | VAF 125/590 reads (21%) | called by muse, mutect2, varscan2
- PAQR7 | c.639C>T p.A213= | Silent (SNP) | VAF 136/399 reads (34%) | catalogued as COSV65351460; called by muse, mutect2, varscan2
- PDGFRB | c.585G>A p.G195= | Silent (SNP) | VAF 119/314 reads (38%) | called by muse, mutect2, varscan2
- PHC1 | c.2211C>T p.I737= | Silent (SNP) | VAF 24/411 reads (6%) | called by muse, mutect2
- PKP3 | c.1366C>T p.L456= | Silent (SNP) | VAF 137/468 reads (29%) | catalogued as rs147705102; called by muse, mutect2, varscan2
- PLIN4 | c.513G>A p.G171= (on ENST00000301286; = p.G186= on NM_001367868.2) | Silent (SNP) | VAF 147/548 reads (27%) | catalogued as COSV100012694; called by muse, mutect2, varscan2
- PNPLA2 | c.1497C>T p.I499= | Silent (SNP) | VAF 130/411 reads (32%) | called by muse, mutect2, varscan2
- PNPLA6 | c.1569C>T p.L523= (on ENST00000414982 / NM_001166111.2; = p.L475= on NM_006702.5) | Silent (SNP) | VAF 93/376 reads (25%) | catalogued as COSV55380510; called by muse, mutect2, varscan2
- POTEH | c.597G>A p.K199= | Silent (SNP) | VAF 65/331 reads (20%) | catalogued as COSV58886472, COSV58887965; called by muse, mutect2, varscan2
- PRRX1 | c.393G>A p.V131= | Silent (SNP) | VAF 78/349 reads (22%) | called by muse, mutect2, varscan2
- PWWP3B | c.171C>T p.I57= | Silent (SNP) | VAF 121/447 reads (27%) | called by muse, mutect2, varscan2
- PXDNL | c.2949G>A p.T983= | Silent (SNP) | VAF 140/508 reads (28%) | catalogued as COSV62479769; called by muse, mutect2, varscan2
- RARG | c.1080C>T p.A360= | Silent (SNP) | VAF 132/469 reads (28%) | called by muse, mutect2, varscan2
- RIMBP2 | c.1284G>A p.E428= | Silent (SNP) | VAF 132/461 reads (29%) | catalogued as rs764972609; called by muse, mutect2, varscan2
- RUNX1T1 | c.453C>T p.L151= (on ENST00000265814 / NM_001198628.1; = p.L124= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as rs749999124; called by muse, mutect2, varscan2
- RYR3 | c.8376G>A p.V2792= (on ENST00000389232; = p.V2793= on NM_001036.6) | Silent (SNP) | VAF 63/248 reads (25%) | catalogued as rs1162045121; called by muse, mutect2, varscan2
- SALL1 | c.1932C>T p.S644= | Silent (SNP) | VAF 127/488 reads (26%) | called by muse, mutect2, varscan2
- SCARA5 | c.945G>A p.G315= | Silent (SNP) | VAF 109/423 reads (26%) | catalogued as COSV57279002; called by muse, mutect2
- SCN11A | c.4596C>T p.F1532= | Silent (SNP) | VAF 82/278 reads (29%) | called by muse, mutect2, varscan2
- SCN1A | c.2658C>T p.S886= (on ENST00000303395 / NM_001202435.3; = p.S875= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as rs776714907, COSV57660002; called by muse, mutect2, varscan2
- SEMA4F | c.975C>T p.I325= | Silent (SNP) | VAF 76/306 reads (25%) | called by muse, mutect2, varscan2
- SERINC5 | c.514C>T p.L172= | Silent (SNP) | VAF 87/245 reads (36%) | called by muse, mutect2, varscan2
- SERPINA10 | c.645G>A p.G215= | Silent (SNP) | VAF 105/396 reads (27%) | catalogued as rs367966236; called by muse, mutect2, varscan2
- SF3B2 | c.1884C>T p.V628= | Silent (SNP) | VAF 92/340 reads (27%) | catalogued as COSV59427756; called by muse, mutect2, varscan2
- SLAMF1 | c.588C>T p.L196= | Silent (SNP) | VAF 270/653 reads (41%) | catalogued as rs772729449, COSV52497430; called by muse, mutect2, varscan2
- SLC28A1 | c.888G>A p.L296= | Silent (SNP) | VAF 98/342 reads (29%) | called by muse, mutect2, varscan2
- SLC6A8 | c.1476G>C p.V492= | Silent (SNP) | VAF 78/310 reads (25%) | called by muse, mutect2, varscan2
- SOWAHC | c.1539G>A p.S513= | Silent (SNP) | VAF 71/267 reads (27%) | catalogued as COSV61780367; called by muse, mutect2, varscan2
- SYNPO2L | c.45C>T p.A15= | Silent (SNP) | VAF 127/286 reads (44%) | catalogued as rs867344709; called by muse, mutect2, varscan2
- TEDDM1 | c.252G>A p.V84= | Silent (SNP) | VAF 103/481 reads (21%) | called by muse, mutect2, varscan2
- TENM4 | c.6834C>T p.I2278= | Silent (SNP) | VAF 123/444 reads (28%) | called by muse, mutect2, varscan2
- TEX13C | c.54C>T p.I18= | Silent (SNP) | VAF 95/328 reads (29%) | called by muse, mutect2, varscan2
- TMEM109 | c.306C>T p.I102= | Silent (SNP) | VAF 74/291 reads (25%) | catalogued as rs756084678; called by muse, mutect2, varscan2
- TMEM217 | c.438C>T p.V146= | Silent (SNP) | VAF 75/395 reads (19%) | catalogued as rs1481391027; called by muse, mutect2, varscan2
- TRDN | c.2058C>T p.I686= | Silent (SNP) | VAF 66/180 reads (37%) | catalogued as COSV62121963; called by muse, mutect2, varscan2
- XRN1 | c.4353C>T p.S1451= | Silent (SNP) | VAF 83/279 reads (30%) | catalogued as rs139447998; called by muse, mutect2, varscan2
- ZNF454 | c.1029C>T p.F343= | Silent (SNP) | VAF 102/283 reads (36%) | catalogued as rs267600577, COSV60768784; called by muse, mutect2, varscan2
- ZNF516 | c.1293C>T p.A431= | Silent (SNP) | VAF 124/471 reads (26%) | catalogued as rs762139524, COSV71587656; called by muse, mutect2, varscan2
- AC244258.1 | n.795C>T | RNA (SNP) | VAF 41/156 reads (26%) | catalogued as rs773538877; called by muse, mutect2, varscan2
- APOBEC3F | c.172-811C>T | Intron (SNP) | VAF 123/434 reads (28%) | catalogued as rs761215753; called by muse, mutect2, varscan2
- IGFN1 | c.1241+902G>A | Intron (SNP) | VAF 107/487 reads (22%) | called by muse, mutect2, varscan2
- LACTBL1 | c.389+23C>T | Intron (SNP) | VAF 86/382 reads (23%) | catalogued as rs1288676861; called by muse, mutect2, varscan2
- MBD5 | c.2845+219C>T | Intron (SNP) | VAF 73/314 reads (23%) | catalogued as rs1181595893; called by muse, mutect2, varscan2
- SKOR2 | c.2753-162G>A | Intron (SNP) | VAF 69/253 reads (27%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2331_1459+2332del | Intron (DEL) | VAF 59/284 reads (21%) | catalogued as rs1201058412; called by pindel, varscan2
- Z99774.2 | chr22:26669329 C>T | 5'Flank (SNP) | VAF 74/300 reads (25%) | called by muse, mutect2, varscan2
